Somatic mutation profile of tumor specimen MMRF_2306_1_BM_CD138pos (aliquot MMRF_2306_1_BM_CD138pos_T2_KHS5U_K14055) from MMRF case MMRF_2306, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 40.7 years (14,857 days).
Specimen MMRF_2306_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14b3225b-5194-45e9-9701-a3a4f445321d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2306_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2306_1_PB_Whole_C1_KHS5U_K14054; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12b9f304-6d02-4401-ad25-a0472287c184

The open-access MAF lists 150 somatic variants for this specimen: 59 protein-altering or splice-affecting, 24 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 38, Silent 24, Intron 17, 5'UTR 8, Nonsense Mutation 5, Splice Site 3, Splice Region 2, 5'Flank 2, RNA 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.*22C>G | 3'UTR (SNP) | VAF 17/42 reads (40%) | catalogued as rs104894362, CM070970, COSV55666258, COSV56095155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATRN | c.3953G>A p.R1318Q | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as rs761701049; called by muse, mutect2, varscan2
- BCL7A | c.92+1G>T p.X31_splice | Splice Site (SNP) | VAF 27/47 reads (57%) | catalogued as rs780433687, COSV55846678, COSV55850485; called by muse, mutect2, varscan2
- COL11A1 | c.4588C>T p.P1530S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.412); catalogued as COSV62175752; called by muse, mutect2, varscan2
- COL4A2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV64635191; called by muse, mutect2, varscan2
- DNAH5 | c.13079C>T p.A4360V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); catalogued as COSV54255538; called by muse, mutect2, varscan2
- ERCC4 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as rs1279163402; called by muse, mutect2
- ERICH6B | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1255766537; called by muse, mutect2
- EXTL3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.771); catalogued as rs777463050, COSV55036819; called by muse, mutect2, varscan2
- FBXW7 | c.845C>T p.S282L (on ENST00000281708 / NM_001349798.2; = p.S202L on NM_018315.5) | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55899012; called by muse, mutect2, varscan2
- FEZ2 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs748261267; called by muse, mutect2, varscan2
- FHOD3 | c.3704G>A p.R1235Q (on ENST00000359247 / NM_001281739.3; = p.R1252Q on NM_025135.5) | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.834); catalogued as rs1015303591; called by muse, mutect2, varscan2
- IGKV4-1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as rs758803569; called by muse, mutect2, varscan2
- IGLV3-1 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as rs577900423; called by muse, varscan2
- IGLV3-1 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as rs374018767; called by muse, mutect2, varscan2
- LLGL2 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450684805, COSV51347815; called by muse, mutect2, varscan2
- MAK | c.1810C>T p.Q604* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | catalogued as rs1490967908; called by muse, mutect2, varscan2
- MMP12 | c.1101C>A p.S367R | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); catalogued as COSV58262026; called by muse, mutect2, varscan2
- MYH13 | c.5545C>T p.R1849C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs559233974, COSV99354128; called by muse, mutect2, varscan2
- PDE4A | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.056); catalogued as COSV100764271; called by muse, mutect2, varscan2
- RESF1 | c.3688C>T p.Q1230* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV57022268; called by muse, mutect2, varscan2
- SOX6 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs745532158, COSV100322502, COSV100323324; called by muse, mutect2, varscan2
- SYNE1 | c.9685C>G p.Q3229E (on ENST00000367255 / NM_182961.4; = p.Q3236E on NM_033071.3) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.487); catalogued as COSV99557951; called by muse, mutect2, varscan2
- UQCRC2 | c.1125G>A p.K375= | Splice Region (SNP) | VAF 7/20 reads (35%) | catalogued as rs769137921; called by muse, mutect2, varscan2
- ZNF331 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV53475494; called by muse, mutect2
- ZNF90 | c.1386C>G p.F462L | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV69002202; called by muse, mutect2, varscan2
- ARHGEF39 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- BLM | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- BRWD1 | c.6333G>C p.K2111N | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- CAAP1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD5 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2
- CHFR | c.970T>C p.F324L (on ENST00000432561 / NM_001161345.1; = p.F283L on NM_018223.2) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYP2W1 | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIDO1 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DUSP2 | c.388+1G>A p.X130_splice | Splice Site (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- FAT4 | c.14654A>T p.N4885I | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- GABRG2 | c.1198G>T p.V400F (on ENST00000361925 / NM_001375343.1; = p.V360F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR182 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 93/175 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- GSK3B | c.1072G>T p.A358S (on ENST00000264235 / NM_001146156.2; = p.A371S on NM_002093.4) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1217 | c.5161G>T p.G1721C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- KMT2C | c.12316C>A p.H4106N | Missense Mutation (SNP) | VAF 164/542 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- MROH5 | c.3177G>C p.L1059F | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- MUC16 | c.28619C>G p.S9540* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- NHLRC1 | c.1162A>T p.K388* | Nonsense Mutation (SNP) | VAF 101/216 reads (47%) | called by muse, mutect2, varscan2
- NME6 | c.-116+5G>A | Splice Region (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- NUP98 | c.5353C>T p.P1785S (on ENST00000359171 / NM_001365126.1; = p.P1768S on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2
- OR2AK2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 104/182 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- OR8B8 | c.311_312del p.F104Sfs*7 | Frame Shift Del (DEL) | VAF 64/199 reads (32%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1942A>T p.T648S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR3 | c.10993-1G>A p.X3665_splice (on ENST00000389232; = p.X3666_splice on NM_001036.6) | Splice Site (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SLC25A17 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SLC6A15 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SNRK | c.1770T>G p.S590R | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); called by muse, mutect2
- TRIM21 | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TUSC1 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- USH2A | c.6352T>A p.F2118I | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZFP28 | c.2156A>T p.H719L | Missense Mutation (SNP) | VAF 141/227 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFYVE27 | c.1205G>T p.C402F | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF729 | c.1013A>C p.H338P | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM2B | c.342C>G p.P114= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- ANPEP | c.1065G>A p.E355= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as COSV100263261; called by muse, mutect2, varscan2
- CACNA1H | c.5121G>T p.L1707= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- CASP6 | c.747C>T p.L249= | Silent (SNP) | VAF 31/157 reads (20%) | called by muse, mutect2, varscan2
- CMPK2 | c.393C>T p.F131= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- COL14A1 | c.1059T>C p.T353= | Silent (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2754G>A p.K918= (on ENST00000402739 / NM_001282597.3; = p.K870= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/165 reads (24%) | catalogued as rs1418916198; called by muse, mutect2, varscan2
- CYP1A2 | c.1260G>A p.L420= | Silent (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- ENDOD1 | c.1269T>A p.I423= | Silent (SNP) | VAF 68/196 reads (35%) | called by muse, mutect2, varscan2
- ENKD1 | c.315G>A p.L105= | Silent (SNP) | VAF 72/85 reads (85%) | catalogued as COSV54669916; called by muse, mutect2, varscan2
- FYCO1 | c.2463G>A p.R821= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV56114249; called by muse, mutect2, varscan2
- IDH2 | c.1296G>A p.L432= | Silent (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- IFT80 | c.1554C>T p.C518= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs1163987189; called by muse, mutect2, varscan2
- IGLV3-1 | c.336C>T p.S112= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs73880716; called by muse, mutect2, varscan2
- KRT31 | c.1233C>T p.C411= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as rs1037054386; called by muse, mutect2
- METAP2 | c.57T>C p.D19= | Silent (SNP) | VAF 38/76 reads (50%) | called by muse, varscan2
- OBSCN | c.6237C>T p.L2079= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs572093306; called by muse, mutect2
- OR10P1 | c.894G>A p.V298= | Silent (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- RITA1 | c.582G>A p.L194= | Silent (SNP) | VAF 94/201 reads (47%) | called by muse, mutect2, varscan2
- RREB1 | c.4392G>A p.A1464= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs779416700, COSV58553718; called by muse, mutect2, varscan2
- SALL4 | c.2547G>A p.S849= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs780919557, COSV53849736; called by muse, mutect2, varscan2
- SCAI | c.303C>G p.L101= (on ENST00000336505 / NM_001144877.3; = p.L124= on NM_173690.5) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV100332092; called by muse, mutect2, varscan2
- SPATA9 | c.156A>G p.R52= | Silent (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- SYNE1 | c.9684T>G p.P3228= (on ENST00000367255 / NM_182961.4; = p.P3235= on NM_033071.3) | Silent (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- ACAT1 | c.-12C>T | 5'UTR (SNP) | VAF 25/75 reads (33%) | catalogued as rs112219560; called by muse, mutect2, varscan2
- ARSD | c.*3200C>T | 3'UTR (SNP) | VAF 26/49 reads (53%) | catalogued as rs1431653866; called by muse, mutect2, varscan2
- BAP1 | c.*229C>T | 3'UTR (SNP) | VAF 14/30 reads (47%) | catalogued as rs1162517138; called by muse, mutect2, varscan2
- BTNL9 | c.*707G>C | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- C1orf194 | c.315-134C>G | Intron (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- CD163L1 | c.124+2038A>C | Intron (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- CLIC4 | c.182+26C>G | Intron (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- CLIC6 | c.*1463T>G | 3'UTR (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- CNTN5 | c.*1638C>T | 3'UTR (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- COX7A2L | c.*73del | 3'UTR (DEL) | VAF 4/36 reads (11%) | called by pindel, varscan2
- CREB3L2 | c.*399A>G | 3'UTR (SNP) | VAF 51/78 reads (65%) | called by muse, mutect2, varscan2
- CSMD3 | c.*569A>C | 3'UTR (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- CSNK2A1 | c.*1218C>A | 3'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- DAW1 | c.973+5201C>G | Intron (SNP) | VAF 116/238 reads (49%) | called by muse, mutect2, varscan2
- DDHD1 | chr14:53152885 C>A | 5'Flank (SNP) | VAF 20/37 reads (54%) | catalogued as COSV99062126; called by muse, mutect2, varscan2
- DDHD1 | chr14:53152975 C>A | 5'Flank (SNP) | VAF 10/18 reads (56%) | called by muse, varscan2
- DPP6 | c.*292A>T | 3'UTR (SNP) | VAF 21/169 reads (12%) | catalogued as COSV100127711; called by muse, mutect2, varscan2
- DSCAM | c.-246C>T | 5'UTR (SNP) | VAF 10/14 reads (71%) | catalogued as rs554717711; called by muse, mutect2, varscan2
- EIF4E | c.*3890C>T | 3'UTR (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- EXOC6B | c.1980+200C>G | Intron (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- EZR | c.12+13del | Intron (DEL) | VAF 72/187 reads (39%) | called by pindel, varscan2
- FGF9 | c.*93C>G | 3'UTR (SNP) | VAF 9/154 reads (6%) | catalogued as COSV101210941; called by muse, mutect2
- FRG2C | c.*995C>T | 3'UTR (SNP) | VAF 22/77 reads (29%) | catalogued as rs199951994; called by muse, mutect2, varscan2
- GABRB3 | c.241-7499C>T | Intron (SNP) | VAF 47/113 reads (42%) | catalogued as rs1364548954; called by muse, mutect2, varscan2
- GXYLT1 | c.*1517A>G | 3'UTR (SNP) | VAF 45/77 reads (58%) | called by muse, mutect2, varscan2
- H6PD | c.*4092C>T | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- IER5L | c.*882G>A | 3'UTR (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- IGIP | c.-1568G>A | 5'UTR (SNP) | VAF 28/56 reads (50%) | catalogued as rs894017487; called by muse, mutect2, varscan2
- IRAK3 | c.*2840G>T | 3'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- ITPRID1 | c.-19-3527G>C | Intron (SNP) | VAF 58/87 reads (67%) | called by muse, mutect2, varscan2
- KCNK12 | c.*8133C>T | 3'UTR (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- KHNYN | c.-17-428C>T | Intron (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- LIPC | c.88+145C>T | Intron (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1551+422G>A | Intron (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2
- MED28 | c.*921G>C | 3'UTR (SNP) | VAF 47/71 reads (66%) | called by muse, mutect2, varscan2
- METAP2 | c.-24T>C | 5'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, varscan2
- MUC16 | c.-51C>T | 5'UTR (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- NDUFA3 | c.10+88G>A | Intron (SNP) | VAF 24/74 reads (32%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.1267G>A | RNA (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2
- NUP160 | c.1686+90G>A | Intron (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- NXN | c.*611C>T | 3'UTR (SNP) | VAF 40/73 reads (55%) | called by muse, mutect2
- OPCML | c.*1522G>A | 3'UTR (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- PCDH17 | c.*3363A>G | 3'UTR (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- PCF11 | c.-373C>G | 5'UTR (SNP) | VAF 78/148 reads (53%) | called by muse, mutect2, varscan2
- PDCD4 | c.*1887C>G | 3'UTR (SNP) | VAF 29/111 reads (26%) | called by muse, mutect2, varscan2
- RAB20 | c.*191C>T | 3'UTR (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- RAB3B | c.*7240G>C | 3'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- REEP4 | c.-341G>A | 5'UTR (SNP) | VAF 3/51 reads (6%) | catalogued as rs898576233; called by muse, mutect2
- RELN | c.*773C>G | 3'UTR (SNP) | VAF 79/132 reads (60%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.*1845C>A | 3'UTR (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- SCLT1 | c.-189C>T | 5'UTR (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- SGPL1 | c.*1844C>T | 3'UTR (SNP) | VAF 13/28 reads (46%) | catalogued as rs937654095; called by muse, mutect2, varscan2
- SLC26A7 | c.*1228G>A | 3'UTR (SNP) | VAF 17/36 reads (47%) | catalogued as rs1036158584; called by muse, mutect2, varscan2
- SLC7A11 | c.*2578G>T | 3'UTR (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*2950T>G | 3'UTR (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- STAT4 | c.273+14998C>T | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- STXBP2 | c.247-30C>G | Intron (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- TADA2B | c.*482C>T | 3'UTR (SNP) | VAF 90/136 reads (66%) | catalogued as rs531388439; called by muse, mutect2, varscan2
- TFAM | c.*4141C>T | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- TRIM55 | c.*793A>T | 3'UTR (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- TSNARE1 | c.1446+3341G>C | Intron (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2
- UBE3B | c.630+251G>C | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2
- UFD1 | chr22:19448303 G>C | 3'Flank (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- VSIG10 | c.*228G>C | 3'UTR (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- ZNF175 | c.*1314G>A | 3'UTR (SNP) | VAF 73/205 reads (36%) | called by muse, mutect2, varscan2
- ZSWIM5 | c.*1487C>T | 3'UTR (SNP) | VAF 88/182 reads (48%) | called by muse, mutect2, varscan2
